HCMI case HCM-EXPT-1227-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/af28043e-c85c-48cf-aa29-853fa0407cf0

Demographics
Sex at birth: female; Days to birth: -28,672 days (78.5 years before the index date).

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.2; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Ascending colon; Classification of tumor: primary; Uicc staging system edition: 7th.

Biospecimens (1 sample)
- Sample HCM-EXPT-1227-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
